Somatic mutation profile of tumor specimen 0DR6YA from CCDI case PBCFCE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Tumor cells, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.4 years (496 days).
Specimen 0DR6YA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e681159-cb32-4090-a118-df919ae040f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR6Y0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/264217ba-4c3c-45dc-8db7-e386bbc02ad8

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1, Splice Site 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM89A | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 152/542 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.062); catalogued as rs960483853; called by muse, mutect2, varscan2
- MPZL3 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 612/848 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBBP6 | c.4739_4742del p.K1580Sfs*38 | Frame Shift Del (DEL) | VAF 667/1022 reads (65%) | called by mutect2, pindel, varscan2
- ZMYM2 | c.1300-1G>C p.X434_splice | Splice Site (SNP) | VAF 162/433 reads (37%) | called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 24/490 reads (5%) | called by muse, mutect2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 10/148 reads (7%) | catalogued as rs1012935800, COSV58726711; called by muse, mutect2
